Somatic mutation profile of tumor specimen TCGA-BP-4991-01A (aliquot TCGA-BP-4991-01A-01D-1462-08) from TCGA case TCGA-BP-4991, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.0 years (19,739 days).
Specimen TCGA-BP-4991-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1afe37a3-0fcf-413c-84c0-f4b8b5d6e0ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4991-11A (Solid Tissue Normal), aliquot TCGA-BP-4991-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de4bab9b-faae-4251-9b06-9a082efc98cb

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 23, Silent 14, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.3386G>T p.G1129V | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50789877; called by muse, mutect2, varscan2
- APBA2 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs199985120, COSV68792040; called by muse, mutect2, varscan2
- COL5A3 | c.4947C>A p.Y1649* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV53418003; called by muse, mutect2, varscan2
- CREM | c.817G>A p.G273R (on ENST00000429130; = p.G228R on NM_181571.3) | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs1210226235, COSV59766206; called by muse, mutect2, varscan2
- DNAH3 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54546794; called by muse, mutect2, varscan2
- DSCAML1 | c.2653G>T p.G885W (on ENST00000321322; = p.G825W on NM_020693.4) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58401230, COSV58405056; called by muse, mutect2, varscan2
- FCRL1 | c.1090C>A p.Q364K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV63826726; called by muse, mutect2, varscan2
- GJA5 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs906244249, COSV54786303; called by muse, mutect2, varscan2
- GLI2 | c.1717G>T p.G573C (on ENST00000361492 / NM_001374353.1; = p.G590C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58050170; called by muse, mutect2, varscan2
- GUCY2F | c.2464G>T p.D822Y | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54307510; called by muse, mutect2, varscan2
- HUWE1 | c.4868G>T p.R1623L | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV53346497; called by muse, mutect2, varscan2
- MPO | c.1640T>C p.L547P | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV51861955; called by muse, varscan2
- MSN | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV64305328; called by muse, mutect2, varscan2
- NOL9 | c.1430C>A p.A477D | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs778063428, COSV66626858; called by muse, mutect2, varscan2
- PLXNC1 | c.2664A>C p.Q888H | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as COSV51582258; called by muse, mutect2, varscan2
- POLG2 | c.1324T>A p.L442M | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV73376993; called by muse, mutect2, varscan2
- RHOT2 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.029); catalogued as COSV53466818; called by muse, mutect2
- SERPINA1 | c.1148C>A p.S383Y | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); catalogued as COSV63346285; called by muse, mutect2, varscan2
- SLC12A4 | c.2165A>C p.K722T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50454833; called by muse, mutect2
- SLC7A11 | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.967); catalogued as COSV54933010; called by muse, mutect2, varscan2
- SLC7A8 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57555757; called by muse, mutect2, varscan2
- SPAM1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749343447, COSV56147094, COSV99773504; called by muse, mutect2, varscan2
- TRIM25 | c.672A>C p.R224S | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV57545523; called by muse, mutect2, varscan2
- TRRAP | c.4948G>T p.V1650L (on ENST00000359863 / NM_001244580.1; = p.V1632L on NM_003496.3) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV62852888; called by muse, mutect2, varscan2
- WDR26 | c.1412C>A p.A471E (on ENST00000414423 / NM_001379403.1; = p.A371E on NM_025160.7) | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54359584; called by muse, mutect2, varscan2
- CNGB3 | c.421_426del p.Q141_R142del | In Frame Del (DEL) | VAF 107/539 reads (20%) | called by mutect2, pindel, varscan2
- DSTYK | c.2100del p.Y700* | Frame Shift Del (DEL) | VAF 90/373 reads (24%) | called by mutect2, pindel, varscan2
- RNF19B | c.2088del p.S697Rfs*15 | Frame Shift Del (DEL) | VAF 40/189 reads (21%) | called by mutect2, pindel, varscan2
- SLC25A3 | c.1028dup p.R344Sfs*33 (on ENST00000228318 / NM_005888.3; = p.R343Sfs*33 on NM_002635.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 31/182 reads (17%) | called by mutect2, pindel, varscan2
- TOB1 | c.582_583del p.N194Kfs*4 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- VHL | c.359_370del p.R120_G123del | In Frame Del (DEL) | VAF 60/199 reads (30%) | called by mutect2, pindel, varscan2
- C6orf47 | c.433T>C p.L145= | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as rs757383485, COSV63264121; called by muse, mutect2, varscan2
- CNTF | c.405C>G p.P135= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV60161493; called by muse, mutect2
- ECSIT | c.822C>T p.A274= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1350976010, COSV52940762; called by muse, mutect2, varscan2
- EFCAB5 | c.2994G>A p.P998= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs1007100228, COSV57935960; called by muse, mutect2, varscan2
- FASN | c.2311C>T p.L771= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV60760378; called by muse, mutect2, varscan2
- FRMPD2 | c.1587G>A p.E529= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV59722850; called by muse, varscan2
- GGT1 | c.228G>A p.G76= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV50644557; called by muse, mutect2, varscan2
- HOXB13 | c.72G>A p.G24= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV51707080; called by muse, mutect2, varscan2
- HTR2A | c.39A>T p.S13= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV66328283; called by muse, mutect2
- KRT35 | c.708G>A p.E236= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV55844426; called by muse, varscan2
- MEGF9 | c.522C>T p.T174= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV64237431; called by muse, mutect2, varscan2
- MFGE8 | c.462C>T p.Y154= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV51557625; called by muse, mutect2, varscan2
- OR51E1 | c.726T>G p.T242= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV67810850; called by muse, mutect2, varscan2
- TM6SF1 | c.951T>A p.L317= | Silent (SNP) | VAF 60/209 reads (29%) | catalogued as COSV51946135; called by muse, mutect2, varscan2
